Surgical pathology report (de-identified scan), TCGA case TCGA-BR-8366, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Asterand, specimen TCGA-BR-8366-01A (Primary Tumor).

[page 1 of 3]
[REDACTED] Case ID	Gross Description	Microscopic Description
[REDACTED]	Stomach segment with a plate-like tumour of 7.5 x 9 cm in its size, with perigastric fat invasion. Greater and lesser curvature lymph nodes are hyperemic, soft.	Adenocarcinoma of the stomach, G3, with perigastric fat invasion. Fifteen examined lymph nodes demonstrated reactive follicular hyperplasia.

[page 2 of 3]
Diagnosis Details	Comments	Formatted Path Report
Tumor Features: Ulcerated, Tumor Extent: Perigastric fat , Venous Invasion: Absent, Margins: Absent, Treatment Effect:		STOMACH TISSUE CHECKLIST Specimen type: Subtotal gastrectomy Tumor site: Fundus Tumor size: 9 x 0 x 7.5 cm Tumor features: Ulcerated Histologic type: Adenocarcinoma Histologic grade: Poorly differentiated Tumor extent: Subserosa Lymph nodes: 0/15 positive for metastasis (Greater and lesser omentum 0/15) Lymphatic invasion: Not specified Venous invasion: Absent Perineural invasion: Not specified Margins: Uninvolved Evidence of neo-adjuvant treatment: Not specified Additional pathologic findings: Not specified Comments: None

[page 3 of 3]
	ID	Excision Date	Laterality

Source: NCI Genomic Data Commons file 6fd8ae3f-283d-4288-9eef-7d109cf037a4 (TCGA-BR-8366.BEBB26AB-E0E5-44C2-9FEB-47EBFC57CBCF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).